Somatic mutation profile of tumor specimen ALCH-B41R-TTP1-A (aliquot ALCH-B41R-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B41R, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 46.9 years (17,145 days).
Specimen ALCH-B41R-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60a094d6-386b-40e1-8dcd-42fe11d7e787.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B41R-NB1-A (Blood Derived Normal), aliquot ALCH-B41R-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/202cd3ec-1a1b-467c-ba65-e88296a5c135

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 18, Silent 7, Frame Shift Del 2, Splice Region 1, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.2644C>G p.Q882E | Missense Mutation (SNP) | VAF 45/469 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.14); catalogued as rs1325417202; called by muse, mutect2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 16/128 reads (13%) | catalogued as rs754135731; called by mutect2, varscan2*
- IGF2BP1 | c.1355G>A p.R452H | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764506936, COSV51731083; called by muse, mutect2, varscan2
- KIAA0753 | c.2513G>T p.R838L | Missense Mutation (SNP) | VAF 34/328 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.093); catalogued as rs765004531, COSV100810515; called by muse, mutect2, varscan2
- OR14C36 | c.218C>A p.S73Y | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV58602555, COSV58603090; called by muse, mutect2
- REV1 | c.1312G>T p.D438Y | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99300648; called by muse, mutect2
- TF | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs747289519, COSV53918470; called by muse, mutect2
- USP4 | c.2078C>T p.T693I | Missense Mutation (SNP) | VAF 38/708 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs748957590; called by muse, mutect2
- DERL2 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 19/101 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EPDR1 | c.44del p.G15Vfs*71 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel, varscan2
- FBXL13 | c.903del p.S302Vfs*16 | Frame Shift Del (DEL) | VAF 34/301 reads (11%) | called by mutect2, pindel
- G6PD | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); called by mutect2, varscan2
- GRIN2B | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- HFM1 | c.1683G>A p.Q561= | Splice Region (SNP) | VAF 10/80 reads (13%) | called by mutect2, varscan2
- OPLAH | c.3755G>A p.G1252D | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLCB4 | c.2556G>C p.M852I | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); called by muse, mutect2
- SKI | c.2083C>T p.R695W | Missense Mutation (SNP) | VAF 18/377 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- STIM1 | c.233A>T p.D78V | Missense Mutation (SNP) | VAF 59/494 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- STK31 | c.2080A>T p.S694C | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- THAP5 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- TMEM185A | c.958C>G p.P320A | Missense Mutation (SNP) | VAF 61/1009 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.389); called by muse, mutect2
- TTLL2 | c.520C>G p.L174V | Missense Mutation (SNP) | VAF 15/225 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.18); called by muse, mutect2
- ZC3H6 | c.2390G>A p.G797D | Missense Mutation (SNP) | VAF 52/359 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- IL36A | c.306G>A p.V102= | Silent (SNP) | VAF 77/472 reads (16%) | catalogued as COSV52082939; called by muse, mutect2, varscan2
- LRRC32 | c.768C>T p.L256= | Silent (SNP) | VAF 26/328 reads (8%) | called by muse, mutect2
- NCSTN | c.213G>A p.G71= | Silent (SNP) | VAF 42/616 reads (7%) | catalogued as rs1187658518; called by muse, mutect2
- NDOR1 | c.1038C>T p.C346= | Silent (SNP) | VAF 10/121 reads (8%) | called by muse, mutect2
- PCDHB2 | c.1297C>T p.L433= | Silent (SNP) | VAF 32/473 reads (7%) | catalogued as rs782783548, COSV99164885; called by muse, mutect2
- SYNE2 | c.6117A>G p.L2039= | Silent (SNP) | VAF 28/488 reads (6%) | called by muse, mutect2
- ZC3H6 | c.2568G>A p.L856= | Silent (SNP) | VAF 53/371 reads (14%) | called by muse, mutect2, varscan2
